Somatic mutation profile of tumor specimen HTMCP-03-06-02060-01A (aliquot HTMCP-03-06-02060-01A-01D-4427) from CGCI case HTMCP-03-06-02060, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G1; Age at diagnosis: 54.6 years (19,929 days).
Specimen HTMCP-03-06-02060-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f909429-624d-464c-a20e-389e0de6c569.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02060-10A (Blood Derived Normal), aliquot HTMCP-03-06-02060-10A-01D-4427; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b56105f-9ded-4d15-b870-74fba896475e

The open-access MAF lists 32 somatic variants for this specimen: 20 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 9, Nonsense Mutation 2, Frame Shift Del 1, Frame Shift Ins 1, RNA 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.48T>A p.Y16* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | hotspot (GDC flag); catalogued as rs587782187, CM110154, COSV64288363, COSV64293151, COSV64295030; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COLGALT2 | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368161881; called by muse, mutect2, varscan2
- ETV1 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54137479; called by muse, mutect2, varscan2
- FAT1 | c.10468G>C p.E3490Q | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV71675791; called by muse, mutect2, varscan2
- IGSF21 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as rs770457601, COSV52132239, COSV99244507; called by muse, mutect2, varscan2
- MAEL | c.1268A>G p.Q423R | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.038); catalogued as rs1395366911; called by muse, mutect2, varscan2
- MAP3K1 | c.1883C>G p.S628* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV68124808, COSV99063958; called by muse, mutect2, varscan2
- PEG3 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs151090043; called by mutect2, varscan2
- QSER1 | c.4319G>C p.R1440T (on ENST00000399302; = p.R1569T on NM_001076786.3) | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67900962; called by muse, mutect2, varscan2
- TRPA1 | c.2532G>T p.M844I | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.366); catalogued as COSV51560022; called by muse, mutect2, varscan2
- DOCK2 | c.2912A>G p.E971G | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- IGSF9 | c.3228G>C p.K1076N (on ENST00000368094 / NM_001135050.2; = p.K1060N on NM_020789.4) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ITGAM | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- MACF1 | c.19858_19859del p.L6620Afs*5 (on ENST00000372915; = p.L4665Afs*5 on NM_012090.5) | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | called by mutect2, pindel
- MED13 | c.4027G>C p.D1343H | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MSTO1 | c.297_300dup p.L101Efs*28 | Frame Shift Ins (INS) | VAF 16/78 reads (21%) | called by mutect2, varscan2
- MUC16 | c.27406C>T p.P9136S | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.031); called by muse, mutect2
- RGS3 | c.1802A>T p.E601V (on ENST00000350696 / NM_001282923.2; = p.E489V on NM_017790.4) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRPS1 | c.301C>T p.P101S (on ENST00000220888 / NM_001330599.2; = p.P114S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/249 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.026); called by muse, mutect2
- ZC3H12C | c.336G>C p.L112F | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRG4 | c.6294T>C p.I2098= | Silent (SNP) | VAF 44/239 reads (18%) | called by muse, mutect2, varscan2
- AOPEP | c.297T>C p.F99= | Silent (SNP) | VAF 15/141 reads (11%) | called by muse, mutect2, varscan2
- CYP11B1 | c.1488C>G p.L496= | Silent (SNP) | VAF 8/76 reads (11%) | called by mutect2, varscan2
- FAT3 | c.9273G>A p.L3091= | Silent (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- KCNA5 | c.588C>T p.F196= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV52907189; called by muse, mutect2, varscan2
- MNS1 | c.171C>T p.L57= | Silent (SNP) | VAF 47/168 reads (28%) | catalogued as COSV53069239; called by muse, mutect2, varscan2
- NEB | c.5976C>A p.L1992= | Silent (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- PCDHGA12 | c.1824G>T p.L608= | Silent (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- SGIP1 | c.1749C>T p.I583= | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as rs375102916; called by muse, mutect2, varscan2
- MUC19 | n.10841T>A | RNA (SNP) | VAF 74/455 reads (16%) | called by muse, mutect2, varscan2
- PQBP1 | c.-199T>C | 5'UTR (SNP) | VAF 14/66 reads (21%) | called by mutect2, varscan2
- TANC2 | c.3109+53C>T | Intron (SNP) | VAF 27/229 reads (12%) | catalogued as rs774578503; called by muse, mutect2, varscan2
